Gene-level copy-number profile of tumor specimen TCGA-04-1364-01A from TCGA case TCGA-04-1364, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,294 days).
Specimen TCGA-04-1364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e73359b7-f33f-4a24-b93a-f93196d5719a.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,196 have no estimate.
https://portal.gdc.cancer.gov/files/5061038c-a81a-4a84-af3e-71e1a2372663

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 34; copy number 2: 209; copy number 3: 3,213; copy number 4: 17,098; copy number 5: 14,665; copy number 6: 6,635; copy number 7: 8,427; copy number 8: 2,063; copy number 9: 684; copy number 10: 828; copy number 11: 60; copy number 12: 25; copy number 13: 11; copy number 14: 621; copy number 15: 10; copy number 16: 768; copy number 18: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1364-01): tumor purity 0.9, ploidy 5.58, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,083 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:71,343,427–73,198,853, 18 genes, copy number 10 (within-gene range 5–10): LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10.
- chr8:36,764,445–38,144,076, 39 genes, copy number 10–16 (within-gene range 7–16): RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1.
- chr8:65,155,407–144,261,940, 1,194 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:57,639,455–57,738,603, 1 gene, copy number 9 (within-gene range 3–9): AC027097.2.
- chr18:57,755,394–57,755,500, 1 gene, copy number 9: RNU6-742P.
- chr18:65,423,958–66,069,647, 6 genes, copy number 9: LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1.
- chr19:6,661,253–8,610,735, 101 genes, copy number 12–18 (broad region; genes not listed).
- chr19:15,049,480–17,943,991, 165 genes, copy number 9 (broad region; genes not listed).
- chr19:17,972,025–17,972,117, 1 gene, copy number 9: RNA5SP468.
- chr19:27,757,184–32,072,113, 79 genes, copy number 11–16 (within-gene range 7–16) (broad region; genes not listed).
- chr20:472,498–63,627,101, 1,373 genes, copy number 14–16 (within-gene range 4–16) (broad region; genes not listed).
- chr22:29,432,944–31,662,432, 105 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
